Somatic mutation profile of tumor specimen MP2PRT-PAUPAX-TMP1-A (aliquot MP2PRT-PAUPAX-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUPAX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (868 days).
Specimen MP2PRT-PAUPAX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a07fec3-b2ca-4043-a8e9-290221d2acdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPAX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPAX-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a63a991-640b-49fe-b988-6f4175599f8a

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS15 | c.2341G>A p.V781M | Missense Mutation (SNP) | VAF 216/633 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs538641006, COSV54503510; called by muse, mutect2, varscan2
- CCDC32 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 151/403 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367681812; called by muse, mutect2, varscan2
- IGDCC4 | c.2588C>T p.T863M | Missense Mutation (SNP) | VAF 211/572 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs201101784, COSV61536399; called by muse, mutect2, varscan2
- TLE3 | c.2133C>T p.C711= | Splice Region (SNP) | VAF 91/267 reads (34%) | catalogued as rs764880221; called by muse, mutect2, varscan2
- UBQLN4 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.815); catalogued as rs200073398, COSV64149206; called by muse, mutect2, varscan2
- BRWD3 | c.2463C>A p.D821E | Missense Mutation (SNP) | VAF 89/391 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELSR3 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 106/699 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PLCB2 | c.1065C>T p.C355= | Silent (SNP) | VAF 194/550 reads (35%) | catalogued as rs746374306, COSV53036654; called by muse, mutect2, varscan2
